Gene-level copy-number profile of tumor specimen TCGA-CR-7388-01A from TCGA case TCGA-CR-7388, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 70.4 years (25,728 days).
Specimen TCGA-CR-7388-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3bcf1016-6d45-416a-9664-57d6be5872e3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7388-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5417de14-96a3-449f-8034-014ba3093af0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 15; copy number 2: 4,936; copy number 3: 8,551; copy number 4: 35,604; copy number 5: 4,802; copy number 6: 4,508; copy number 7: 201; copy number 8: 486; copy number 9: 291; copy number 10: 99; copy number 12: 99; copy number 13: 42; copy number 15: 18; copy number 16: 7; copy number 18: 99; copy number 23: 16; copy number 24: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7388-01A-11D-2010-01): tumor purity 0.4, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 660 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,154,985–245,709,432, 1 gene, copy number 9 (within-gene range 6–9): KIF26B.
- chr1:245,614,773–248,919,946, 138 genes, copy number 9 (broad region; genes not listed).
- chr3:174,438,573–175,810,548, 1 gene, copy number 10 (within-gene range 6–10): NAALADL2.
- chr3:175,234,861–183,428,778, 133 genes, copy number 10–24 (within-gene range 8–24) (broad region; genes not listed).
- chr7:78,017,055–79,453,667, 1 gene, copy number 10 (within-gene range 4–10): MAGI2.
- chr7:78,392,626–96,110,322, 202 genes, copy number 9–15 (within-gene range 8–15) (broad region; genes not listed).
- chr11:69,072,915–69,162,440, 1 gene, copy number 10 (within-gene range 4–10): AP003071.5.
- chr11:69,103,493–71,252,577, 49 genes, copy number 10–18 (within-gene range 5–18): AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr12:44,508,275–48,971,735, 134 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
